Gene-level copy-number profile of tumor specimen TCGA-DU-7292-01A from TCGA case TCGA-DU-7292, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 69.2 years (25,266 days).
Specimen TCGA-DU-7292-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.f0d16866-4d37-4588-b994-e723338bab13.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DU-7292-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/75ae6b06-de96-48a1-ae2e-1ec84c331028

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 78; copy number 2: 6,509; copy number 4: 50,836; copy number 5: 116; copy number 9: 2,049; copy number 10: 105; copy number 13: 5; copy number 14: 3; copy number 57: 63; copy number 58: 50.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DU-7292-01A-11D-2023-01): tumor purity 0.99, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 78 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,705,338–19,929,937, 4 genes: C11orf98P1, AL158077.2, AL158077.1, AL591222.1.
- chr9:20,658,309–20,995,955, 1 gene (within-gene range 0–2): FOCAD.
- chr9:20,716,105–24,088,051, 73 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,275 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,212,827–205,211,702, 62 genes, copy number 57 (within-gene range 2–57) (broad region; genes not listed).
- chr1:205,233,821–205,236,867, 1 gene, copy number 57: TMCC2-AS1.
- chr7:54,330,670–159,233,377, 2,091 genes, copy number 9–58 (broad region; genes not listed).
- chr10:3,009,976–5,666,595, 66 genes, copy number 9–10 (broad region; genes not listed).
- chr10:36,432,882–38,719,229, 55 genes, copy number 10: MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA, AL390061.1, MKNK2P1, ARL6IP1P2, ANKRD30A, RNU6-811P, AL157387.1, LINC00993, RN7SL314P, Y_RNA, TMEM161BP1, VN1R53P, TACC1P1, MTND1P18, MTRNR2L7, AL132657.1, ZNF248, AL132657.2, ZNF33BP1, TLK2P2, AL135791.1, ZNF37CP, ZNF33CP, ZNF25, ZNF25-DT, Y_RNA, ZNF33A, RNU6-795P, AL161931.1, EIF3LP3, FXYD6P2, ZNF37A, AL117339.4, AL117339.3, AL117339.1, CCNYL4, AL133217.1, AL117339.2, HSD17B7P2, SEPTIN7P9, AL133216.2, RNU6-1118P, CICP9, AL133216.1, ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
